Surgical pathology report (de-identified scan), TCGA case TCGA-DX-A6BF, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-A6BF-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED]

ICD-O-3
Liposarcoma, dedifferentiated
8858/3
Site: Retroperitoneum
248.0
QW 5/21/13

....
Clinical Diagnosis & History:
Liposarcoma.

Specimens Submitted:

- 1: Right retroperitoneal sarcoma including right colon, right kidney, right tube and ovary
- 2: Additional tumor on duodenum and pancreas
- 3: Small bowel mesenteric

DIAGNOSIS:

1. Retroperitoneum, right, retroperitoneal mass including right colon, right kidney, right tube and ovary; resection:
- Dedifferentiated liposarcoma, arising in a background of well differentiated liposarcoma.
- The tumor is 38.3 cm in largest dimension.
- The dedifferentiated component constitutes 40% of the tumor and shows high-grade spindle and pleomorphic sarcoma like morphology.
- Necrosis is present (25 to 30%) in the dedifferentiated area.
- Well differentiated liposarcoma, lipoma-like and sclerosing type.
- Tumor involves the renal capsule and extends to the serosa of the colon.
- Benign portion of fallopian tube. No definite ovary is identified.
- Margins (renal vascular, ureter and colon) are free of tumor.
2. Additional tumor on duodenum and pancreas; resection:
- Well differentiated liposarcoma, lipoma-like and sclerosing type.
- The tumor is 8.5 cm in largest dimension.
- The tumor extends to the inked resection margins.
- One benign lymph node.
3. Small bowel mesentery; excision:
- Well differentiated liposarcoma, lipoma-like.
- The tumor is 4.5 cm in largest dimension.

Note: The prior biopsy was reviewed.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED

** Continued on next page **

[page 2 of 4]
SURGICAL

Page 2 of 4

THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1) The specimen is received in fresh, labeled "Right retroperitoneal sarcoma, including right colon, right kidney, right tube and ovary" and consists of a 6078.0 g, 38.3 x 26.2 x 19.0 cm soft tissue mass with attached right colon, right kidney, right tube and possible right ovary. The terminal ileum measures 15.2 cm in length and 2.1 cm in circumference at the proximal resection margin. The remaining colon measures 33.6 in length with a circumference of 6.3 cm at the distal resection margin. An appendix is not grossly identified. The right kidney measures 8.6 x 6.1 x 4.3 cm. The right fallopian tube is smooth tan-purple, has an occasional paratubal cyst and measures 6.4 cm in length and 0.3 cm in diameter. Posterior to the right fallopian tube is a 0.8 x 0.3 x 0.2 cm, poorly defined, slightly firm, tan-yellow oblong nodule, possible atrophic ovary. No other ovary is identified grossly. Sectioning of the specimen reveals a 12.1 x 8.8 x 8.5 cm, multilobular, solid, firm to hard, focally calcified and necrotic (roughly 10% necrosis), gritty and whorled, tan-white mass that focally infiltrates into the surrounding adipose tissue and is located inferolateral to the kidney, (designated Mass #1). Also, directly medial to the kidney is an additional mass similar appearing to Mass #1 measuring 12.7 x 10.1 x 9.3 cm. Both Mass #1 and #2 grossly appears to partially abut the kidney and focally adhere to capsule, but does not grossly appear to invade into the kidney parenchyma. The remaining specimen consists of a 34.0 x 25.1 x 13.9 cm, ill-defined, multilobular, rubbery to focally firm, tan-yellow to pale white fatty mass interspersed by thin bands of fibrous tissue, which partially surrounds but does not grossly involve the fallopian tube, randomly runs along and focally adheres to the serosa of the bowel, encases the remaining kidney, is 0.5 cm from the renal vein margin and 6.3 cm from the ureteral margin. Sections through the remainder of the kidney reveal pink brown parenchyma, with a poorly-defined cortico-medullary junction. The cortex measures 0.5 cm and the calyces appear constricted. The bowel margins are grossly uninvolved by tumor. No adrenal gland is identified. Representative sections are submitted. Portions of tumor are submitted to TPS. Photographs are taken.

Summary of sections:

UVM -- ureter and vascular margins, kidney
PM -- proximal margin, bowel
DM -- distal margin, bowel midline
C -- normal colon
F -- Fallopian tube, representative
O -- possible ovary
K -- normal kidney
RVM -- renal vein with possible surrounding soft tissue mass
M1K Mass #1 with kidney
M1 Mass #1, representative

** Continued on next page **

[page 3 of 4]
SURGICAL

----- Page 3 of 4

M2K Mass #2 with kidney

M2 Mass #2, representative

RFM -- remaining fatty mass with surrounding tissue, representative

ADD- additional section from possible adrenal gland

2) The specimen is received fresh, labeled "Additional tumor on duodenum and pancreas", and consists of an 8.5 x 6.4 x 3.1 cm irregular portion of yellow-tan lobulated shaggy tan tissue. There is a previous incision revealing underlying yellow-tan homogenous fatty cut surfaces. Remaining external surface is partially inked green, from which TPS is submitted. The remaining external surface is inked blue. Further sectioning reveals yellow-tan homogenous fatty cut surfaces. A pink-tan rubbery lymph node measuring 2.3 cm in greatest dimension is identified. Representative sections are submitted.

Summary of sections:

RS - representative sections

LN - lymph node, sectioned

3) The specimen is received in formalin labeled "Small bowel mesentery" and consists of a 4.5 x 3.5 x 1.4 cm well-circumscribed tan-yellow to purple membranous adipose tissue. Sectioning displays a tan homogeneous cut surface. No discrete lesion or mass are grossly identified. Representative sections are submitted.

Summer sections:

U- undesignated

Summary of Sections:

Part 1: Right retroperitoneal sarcoma including right colon, right kidney, right tube and ovary

Block	Sect.	Site	PCs
1		ADD	1
1		B	1
1		DM	1
1		F	4
2		K	2
6		M1	6
4		M1K	4

** Continued on next page **

[page 4 of 4]
SURGICAL

Page 4 of 4

7	M2	7
3	M2K	3
1	O	1
1	PM	1
12	RFM	12
1	RVM	1
1	UVM	1

Part 2: Additional tumor on duodenum and pancreas

Block	Sect.	Site	PCs
4		LN	4
4		RS	4

Part 3: Small bowel mesenteric

Block	Sect.	Site	PCs
4		U	4

** End of Report **

Criteria	lw 5/5/13	Yes	No
H&A Discrepancy			✓

Source: NCI Genomic Data Commons file a74d84e6-b2ab-4bc0-ad9f-21bc1dbdfcd8 (TCGA-DX-A6BF.A2BB4652-23E4-462B-958A-E1EBA00834C4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).